Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A147, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A147-01A (Primary Tumor).

ICD C-3
Infiltrating duct carcinoma, NOS
Site: breast, NOS
8500/3
C50.9
11/22/10
page 1 / 1

Department of Cancer Pathology

copy No.
Date:

Examination: Histopathological examination

Examination No.:

Patient PESEL: Age: Gender: F

Material: Partial organ resection – lesion from the left breast – lower outer quadrant

Unit in charge

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the right breast, typical quadrant marking ✓

Examination performed on:

Macroscopic description:

Part of the breast sized 8.8 x 8.3 x 2.4 cm with a skin flap of 5.8 x 2.3 cm, marked typically, with an X-ray image. Tumour cross section sized 1.7 x 1.5 x 2.3 cm. Margins: to the base 0.1 cm; do the skin surface 0.6 cm; to the sternum 2.2 cm, to the axilla 3.6 cm, to the shoulder 2.3 cm, lower 4.3 cm.

Microscopic description:

Carcinoma ductale invasivum: NHG3 (3+3+3: 18 mitoses /10 HPF - diam. 0.55mm), pT2. Solitary DCIS focuses found beneath the tumour (solid type with medium atypia, no necrosis) placed 0.5 cm from the incision line.

Histopathological diagnosis:

Resectio partialis mammae dextrae:

Carcinoma ductale invasivum et ductale in situ (NHG3, pT2).

INVASIVE DUCTAL CARCINOMA AND IN SITU DUCTAL CARCINOMA OF THE RIGHT BREAST

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors in neoplastic cell nuclei not found.

Progesterone receptors in neoplastic cell nuclei not found.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 0)

Compliance validated by:

Reviewed Date		

Source: NCI Genomic Data Commons file 06ab45a0-3341-485c-88f8-f5d3ca9851f1 (TCGA-D8-A147.380639A2-E89C-4495-8168-82120617129F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).